Surgical pathology report (de-identified scan), TCGA case TCGA-UF-A7JS, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-UF-A7JS-01A (Primary Tumor).

ICD O-3

Carcinoma, squamous cell NOS
8070/3

Site Tongue NOS
C02.9

JW 9/24/13

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Tongue

1 - "Lymph Nodes - Level 1, 2 and 3 - Right":

- Twenty-five lymph nodes uninvolved by metastatic carcinoma (0/25).
- Submandibular salivary gland uninvolved by neoplasia.

2 - "Marginal pelviglossomandibulectomy + left medial modified neck dissection specimens":

- Moderately differentiated squamous cell carcinoma of tongue, measured 7.5 x 4.0 cm and 3.5 cm deep, involving skeletal muscle tissue and osseous tissue.
- Lymphatic and perineural invasion: present.
- Vascular invasion: not identified.
- Deep margin of tongue involved by neoplasia.
- Other surgical margins uninvolved by neoplasia.
- Four of nineteen lymph nodes involved by metastatic carcinoma (4/19), without capsular involvement.

3 - "Tongue margin":

- Uninvolved by neoplasia.

Source: NCI Genomic Data Commons file 5de10aa3-04ec-4610-b4f0-b54178f75a05 (TCGA-UF-A7JS.5E4A0411-4257-459B-988A-DB02051039C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).